Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2QB, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2QB-01A (Primary Tumor).

[page 1 of 6]
Date of Procedure:
Date of Receipt:
Date of Original Rep
Date of Amendment
Account #:
Billing Type:
Additional Copy to: **INPATIENT**

Clinical Diagnosis & History:

Papillary thyroid cancer, metastatic papillary carcinoma.

Specimens Submitted:

- 1: Right neck contents level 2
- 2: Right neck contents level 3
- 3: Right neck contents level 4
- 4: Right neck contents level 5
- 5: Soft tissue, central compartment of neck
- 6: Thyroid and central compartment lymph nodes

AMENDED DIAGNOSIS:

1. Right neck contents level 2:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 12

99% follicular per TSS

2. Right neck contents level 3:

Lymph Node Dissection:

Metastatic metastatic papillary carcinoma

Number of lymph nodes examined: 9

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 0.5cm.

Size of the largest metastatic focus: 0.15 cm.

Extranodal extension is not identified

ICD-0-3

Carcinoma, papillary, follicular variant

8340/3

Site: thyroid, NOS C73.9

*pw
9/15/11*

3. Right neck contents level 4:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma

Number of lymph nodes examined: 13

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 2cm.

Size of the largest metastatic focus: 2 cm.

Extranodal extension is not identified

4. Right neck contents level 5:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 3

[page 2 of 6]
5. Soft tissue, central compartment of neck:

Lymph Node Dissection:

Benign fibroadipose tissue

6. Thyroid and central compartment lymph nodes:

Tumor Type:

Multiple foci of papillary carcinoma: One follicular variant with oncocytic features and multiple microcarcinomas

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Psammoma bodies

Tumor Location:

Left lobe

Right lobe

The largest tumor focus is located in the right lobe

Tumor Size:

The tumor foci range from 0.15 cm up to 1.6 cm in greatest dimension

Tumor Encapsulation:

Partially surrounded

For the largest focus

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades: perithyroidal fibroadipose tissue

Surgical Margins:

Tumor is noted focally at the cauterized margin

Tumor Multicentricity:

At least six foci of papillary microcarcinoma are noted in both lobes, ranging from 0.9 to 0.2 cm

Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

Not identified

Lymph Nodes:

Perinodal (extracapsular) extension not identified

Metastatic papillary thyroid carcinoma involving three of seventeen lymph nodes (3/17). In one lymph node the metastasis is represented by psammomatous calcifications. The largest lymph node with metastasis measures 0.23 cm and metastasis measures 0.2 cm

[page 3 of 6]
Note:

This document represents an amended version of the surgical pathology report originally issued on [redacted] That report is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT

Specimen submitted

6. Lymph Nodes:

Perinodal (extracapsular) extension not identified

Metastatic papillary thyroid carcinoma involving three of seventeen lymph nodes (3/17). In one lymph node the metastasis is represented by psammomatous calcifications. The largest lymph node with metastasis measures 0.23 cm and metastasis measures 0.2 cm

AMENDED REPORT

Specimen submitted

6. Lymph Nodes:

Perinodal (extracapsular) extension not identified

Metastatic papillary thyroid carcinoma involving three of seventeen lymph nodes (3/17). In one lymph node the metastasis is represented by psammomatous calcifications. The largest lymph node with metastasis measures 0.23 cm and metastasis measures 0.2 cm

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

M.D.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain
RECUT

Comment

Gross Description:

M.D.

1.) The specimen is received fresh, labeled "right neck contents-level 2" and consists of multiple pink tan firm lymph nodes ranging from 0.2 cm to 2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

M.D.

2.) The specimen is received fresh, labeled "right neck contents-level 3" and consists of multiple pink tan firm lymph nodes ranging from 0.2 cm to 1cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

M.D.

3.) The specimen is received fresh, labeled "right neck contents-level 4" and consists of multiple pink tan firm lymph nodes ranging from 0.2 cm to 2.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

BLN - half of grossly positive lymph node (remaining half submitted for TPS)

[page 4 of 6]
M.D.

4.) The specimen is received fresh, labeled "right neck contents-level 5" and consists of tan-yellow adipose tissue measuring 3.7 x 2.1 x 1 cm. No obvious lymph nodes are identified. The specimen is entirely submitted.

Summary of sections:

U - undesignated

M.D.

5)The specimen is received fresh, labeled "soft tissue, central compartment of neck" and consists of 8x2x0.9 cm portion of soft tissue without orientation. Cut sections reveal lobulated adipose tissue. No lymph node is identified. Representative sections are submitted.

Summary of sections:

U-unspecified

M.D.

6)The specimen is received fresh, labeled "thyroid gland and central component lymph nodes" and consists of a thyroid weighing 20.5 g. The right lobe measures 5.5x2.3x1 cm, the left lobe measures 3x2.5x1.5 cm and the isthmus measures 1x2.2x0.6 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals 7 well circumscribed nodules (3 in right lobe and 4 in left lobe) ranging from 0.4 cm to 1.6 cm in greatest dimension. The largest nodule has tan brown fleshy cut surface and is located within the right lobe. Other nodules have yellowish cut surface. No lymph node is identified. Representative sections of the largest nodule is submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

RL - right lobe

(Cassettes 2&3, 1st nodule; cassette 4, 2nd nodule; cassettes 5&6, 3rd nodule)

LL - left lobe

IS - isthmus

(Cassettes 9&10, 4th and 5th nodules; cassette 11, 6th nodule; cassettes 12 & 13, 7th nodule)

Rest-reminder of the tissue

Summary of Sections:

Part 1: Right neck contents level 2

Block	Sect. Site	PCs
4	LN	4

Part 2: Right neck contents level 3

Block	Sect. Site	PCs
4	LN	4

Part 3: Right neck contents level 4

Block	Sect. Site	PCs
1	BLN	1
3	LN	3

Part 4: Right neck contents level 5

Block	Sect. Site	PCs
2	U	2

Part 5: Soft tissue, central compartment of neck

[page 5 of 6]
Block	Sect. Site	PCs
2	u	2

Part 6: Thyroid and central compartment lymph nodes

Block	Sect. Site	PCs
2	ist	2
6	ll	6
2	rest	2
6	rl	6

Amendments

Amend Date: **Amended By:**

Original Diagnosis:

1. Right neck contents level 2:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 12

2. Right neck contents level 3:

Lymph Node Dissection:

Metastatic metastatic papillary carcinoma

Number of lymph nodes examined: 9

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 0.5cm.

Size of the largest metastatic focus : 0.15 cm.

Extranodal extension is not identified

3. Right neck contents level 4:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma

Number of lymph nodes examined: 13

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 2cm.

Size of the largest metastatic focus : 2 cm.

Extranodal extension is not identified

4. Right neck contents level 5:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 3

5. Soft tissue, central compartment of neck:

Lymph Node Dissection:

Benign fibroadipose tissue

6. Thyroid and central compartment lymph nodes:

Tumor Type:

Multiple foci of papillary carcinoma: One follicular variant with oncocytic features and multiple micro

[page 6 of 6]
Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Psammoma bodies

Tumor Location:

Left lobe

Right lobe

The largest tumor focus is located in the right lobe

Tumor Size:

The tumor foci range from 0.15 cm up to 1.6 cm in greatest dimension

Tumor Encapsulation:

Partially surrounded

For the largest focus

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades:perithyroidal fibroadipose tissue

Surgical Margins:

Tumor is noted focally at the cauterized margin

Tumor Multicentricity:

At least six foci of papillary microcarcinoma are noted in both lobes, ranging from 0.9 to 0.2 cm

Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

Not identified

Lymph Nodes:

Perinodal (extracapsular) extension not identified

Metastatic papillary thyroid carcinoma involving three of seventeen lymph nodes (3/7). In one lymph node the metastasis is represented by psammomatous calcifications. The largest lymph node with metastasis measures 0.23 cm and metastasis measures 0.2 cm

*** Report Electronically Signed Out ***

Signed out by

Referring Physician Contacted

/a email on

Source: NCI Genomic Data Commons file 44545e3d-c493-4046-8927-8305d48ea5c7 (TCGA-DJ-A2QB.8F4F74F6-4B01-4F2D-9927-12F1A23A3501.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).